Somatic mutation profile of tumor specimen ALCH-B1LK-TTP1-A (aliquot ALCH-B1LK-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1LK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 64.8 years (23,651 days).
Specimen ALCH-B1LK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6becffdc-bc14-4957-81af-e2a95c39b7a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1LK-NB1-A (Blood Derived Normal), aliquot ALCH-B1LK-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5493f997-79a8-481d-87b3-3c2621b3a3f8

The open-access MAF lists 201 somatic variants for this specimen: 135 protein-altering or splice-affecting, 44 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 116, Silent 44, Intron 14, Nonsense Mutation 8, Frame Shift Del 6, 3'UTR 3, 5'UTR 3, Splice Region 2, RNA 2, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.7881dup p.S2628Efs*13 | Frame Shift Ins (INS) | VAF 99/588 reads (17%) | catalogued as rs1060501067; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RAC1 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 14/92 reads (15%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 99/217 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AGRN | c.5128G>T p.A1710S | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as rs1357149097; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.862); catalogued as rs770011324, COSV51839754; called by mutect2, varscan2
- ANO10 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 77/174 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs769095178, COSV52733138; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP11A | c.1493G>A p.G498E | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV52117303; called by muse, mutect2, varscan2
- BRCA1 | c.5312C>T p.P1771L | Missense Mutation (SNP) | VAF 193/385 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs80357025; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRINP2 | c.1331C>T p.T444I | Missense Mutation (SNP) | VAF 128/356 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs763167273, COSV64176421; called by muse, mutect2, varscan2
- CD5 | c.1280-1G>C p.X427_splice | Splice Site (SNP) | VAF 47/184 reads (26%) | catalogued as COSV61719105; called by muse, mutect2, varscan2
- CDKN2A | c.334del p.R112Vfs*34 | Frame Shift Del (DEL) | VAF 134/381 reads (35%) | catalogued as CM013695, COSV58684425, COSV58709681, COSV58723857; called by mutect2, pindel, varscan2
- CEP170 | c.733A>G p.T245A | Missense Mutation (SNP) | VAF 92/265 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1462672709; called by muse, mutect2, varscan2
- CERS1 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1009080328; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNDP1 | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 121/286 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV62594673; called by muse, mutect2, varscan2
- COL6A1 | c.344G>C p.S115T | Missense Mutation (SNP) | VAF 25/530 reads (5%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.457); catalogued as rs372627181, COSV62614659; called by muse, mutect2
- CSMD3 | c.4901G>A p.S1634N (on ENST00000297405 / NM_001363185.1; = p.S1530N on NM_052900.3) | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs756177112, COSV99831778; called by muse, mutect2
- CTNND2 | c.2590G>C p.E864Q | Missense Mutation (SNP) | VAF 33/313 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58915145; called by muse, mutect2, varscan2
- DCHS2 | c.917G>C p.R306P | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV59717654; called by muse, mutect2, varscan2
- DNAH14 | c.4048A>G p.I1350V (on ENST00000445597; = p.I1755V on NM_001367479.1) | Missense Mutation (SNP) | VAF 125/356 reads (35%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.573); catalogued as rs1185993524; called by muse, mutect2, varscan2
- DZANK1 | c.960G>A p.M320I (on ENST00000262547 / NM_001099407.1; = p.M121I on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV52753095; called by muse, mutect2, varscan2
- EEFSEC | c.1759G>A p.D587N | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs368381879; called by muse, mutect2, varscan2
- EMILIN1 | c.135G>T p.Q45H | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100980190; called by muse, mutect2, varscan2
- EVC2 | c.3199G>T p.E1067* | Nonsense Mutation (SNP) | VAF 71/496 reads (14%) | catalogued as COSV60391586; called by muse, mutect2, varscan2
- FMN2 | c.3311G>T p.G1104V | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV100147191; called by muse, varscan2
- GHR | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50109830, COSV50135382; called by muse, mutect2, varscan2
- HCN1 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as COSV57537310, COSV57542378; called by muse, mutect2, varscan2
- HUWE1 | c.5455C>G p.L1819V | Missense Mutation (SNP) | VAF 57/93 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53357606; called by muse, mutect2, varscan2
- KMT2D | c.15641G>T p.R5214L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398123729, CM105480, COSV56427001, COSV99977974; called by muse, mutect2, varscan2
- KNTC1 | c.1089T>A p.D363E | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV100338024; called by muse, mutect2, varscan2
- MAN2B1 | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 38/271 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1396515381, COSV55471633; called by muse, mutect2, varscan2
- MTIF3 | c.618G>T p.M206I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100820184; called by muse, mutect2, varscan2
- NES | c.1283T>C p.L428P | Missense Mutation (SNP) | VAF 86/481 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.641); catalogued as rs1274185017; called by muse, mutect2, varscan2
- OR2G6 | c.100T>C p.F34L | Missense Mutation (SNP) | VAF 164/529 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV58573933; called by muse, mutect2, varscan2
- OR2T33 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 36/1140 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV100531497; called by muse, mutect2
- PARD3 | c.3075G>C p.R1025S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV61056284; called by muse, mutect2, varscan2
- PARP14 | c.1992C>A p.F664L | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV71734372; called by muse, mutect2, varscan2
- PDCL2 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV55262523; called by muse, mutect2, varscan2
- PRB1 | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 53/86 reads (62%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs754442633; called by mutect2, varscan2
- PREX2 | c.4082T>A p.V1361D | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99906139; called by muse, mutect2, varscan2
- SCN11A | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.161); catalogued as rs545360453; called by muse, mutect2
- SLAIN2 | c.532A>G p.M178V | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as rs371076921; called by muse, mutect2, varscan2
- TCERG1L | c.875G>A p.G292D | Missense Mutation (SNP) | VAF 70/248 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1248446362; called by muse, mutect2, varscan2
- TENM3 | c.941C>A p.A314D | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101305017, COSV69303779; called by muse, mutect2, varscan2
- TG | c.7669G>C p.E2557Q | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.031); catalogued as rs767107955; called by muse, mutect2, varscan2
- TLL2 | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 129/467 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as rs748097625; called by muse, mutect2, varscan2
- TNFAIP8 | c.331A>G p.M111V | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs1210163488; called by muse, mutect2, varscan2
- UBE3B | c.3086G>T p.R1029L | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61075991; called by muse, mutect2, varscan2
- UPRT | c.89G>C p.R30P | Missense Mutation (SNP) | VAF 61/99 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.401); catalogued as COSV64912625; called by muse, mutect2, varscan2
- ZNF136 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.132); catalogued as rs147268850; called by muse, mutect2, varscan2
- AC083899.1 | n.3161A>C | Splice Region (SNP) | VAF 22/95 reads (23%) | called by mutect2, varscan2
- ADAM10 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS3 | c.21G>T p.W7C | Missense Mutation (SNP) | VAF 48/291 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- AHCTF1 | c.5014C>G p.Q1672E (on ENST00000366508; = p.Q1646E on NM_015446.5) | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AHCTF1 | c.3032T>C p.I1011T (on ENST00000366508; = p.I985T on NM_015446.5) | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP21 | c.3337G>A p.D1113N | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ARHGEF10 | c.3295G>C p.E1099Q (on ENST00000398564; = p.E1074Q on NM_014629.4) | Missense Mutation (SNP) | VAF 37/314 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ARL8B | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- ARPP21 | c.2099A>T p.Q700L | Missense Mutation (SNP) | VAF 83/191 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ASPM | c.9565C>A p.Q3189K | Missense Mutation (SNP) | VAF 128/369 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BCL9 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 30/152 reads (20%) | called by muse, mutect2, varscan2
- BTAF1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C10orf71 | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 85/295 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- C2orf80 | c.189G>A p.W63* | Nonsense Mutation (SNP) | VAF 51/235 reads (22%) | called by muse, mutect2, varscan2
- CCDC102A | c.267G>C p.Q89H | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC173 | c.148A>C p.I50L | Missense Mutation (SNP) | VAF 43/351 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC71L | c.645G>T p.Q215H | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- CDH26 | c.1234G>T p.G412W | Missense Mutation (SNP) | VAF 54/350 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEMIP2 | c.2926C>T p.P976S | Missense Mutation (SNP) | VAF 91/227 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CEP350 | c.806G>T p.R269I | Missense Mutation (SNP) | VAF 50/321 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CKAP2L | c.1923G>C p.E641D | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- CLCN1 | c.2720G>T p.W907L | Missense Mutation (SNP) | VAF 114/361 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CLDN3 | c.283C>G p.L95V | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CP | c.494A>G p.Q165R | Missense Mutation (SNP) | VAF 77/323 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CRYBG1 | c.2855G>C p.R952T | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CRYBG1 | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- CRYBG1 | c.3369G>T p.M1123I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CTNNA1 | c.1316C>G p.S439C | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CUL5 | c.161A>T p.D54V | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- DIP2B | c.1529G>T p.G510V | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- DPP6 | c.743del p.G248Afs*7 (on ENST00000377770 / NM_001364500.2; = p.G186Afs*7 on NM_001936.5) | Frame Shift Del (DEL) | VAF 50/233 reads (21%) | called by mutect2, pindel, varscan2
- DZIP1 | c.1667T>C p.L556S (on ENST00000347108; = p.L537S on NM_014934.5) | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- EEA1 | c.2567C>G p.S856C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- F13A1 | c.740A>T p.Q247L | Missense Mutation (SNP) | VAF 144/440 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FGD5 | c.1311del p.G438Vfs*25 | Frame Shift Del (DEL) | VAF 44/147 reads (30%) | called by mutect2, pindel, varscan2
- FLNA | c.4570C>G p.L1524V | Missense Mutation (SNP) | VAF 188/293 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FSCB | c.392C>A p.S131Y | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FTCD | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- GIMAP2 | c.940T>C p.F314L | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GLT8D1 | c.983A>G p.H328R | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR39 | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 42/296 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- HOXA5 | c.589A>G p.R197G | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFIH1 | c.2734_2736delinsTT p.V912Ffs*2 | Frame Shift Del (DEL) | VAF 37/167 reads (22%) | called by pindel, varscan2*
- INSYN2A | c.1333C>A p.Q445K | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- INTS13 | c.1806A>G p.R602= | Splice Region (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2
- KCNN2 | c.192_198del p.E65Wfs*102 (on ENST00000264773; = p.E277Wfs*102 on NM_021614.4) | Frame Shift Del (DEL) | VAF 86/257 reads (33%) | called by mutect2, pindel, varscan2
- KMT2D | c.11249del p.Q3750Rfs*80 | Frame Shift Del (DEL) | VAF 108/393 reads (27%) | called by mutect2, pindel, varscan2
- KREMEN2 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KSR2 | c.986+2T>C p.X329_splice | Splice Site (SNP) | VAF 67/393 reads (17%) | called by muse, mutect2, varscan2
- LPCAT1 | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 32/424 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2
- MAP3K4 | c.1673G>T p.R558L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAPK8IP3 | c.349C>G p.Q117E | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- MSH3 | c.1371G>C p.R457S | Missense Mutation (SNP) | VAF 97/214 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- MTARC2 | c.914A>C p.E305A | Missense Mutation (SNP) | VAF 126/323 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NKX2-5 | c.581A>G p.K194R | Missense Mutation (SNP) | VAF 161/420 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- NMU | c.428G>C p.R143T | Missense Mutation (SNP) | VAF 93/292 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NYAP1 | c.646T>A p.Y216N | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OLFML3 | c.749C>A p.T250K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.321); called by mutect2, varscan2
- OR2T8 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2
- OR8K3 | c.200C>A p.A67D | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- PALLD | c.2158G>C p.V720L | Missense Mutation (SNP) | VAF 70/416 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PCLO | c.3505G>A p.E1169K | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- PDCD1LG2 | c.794C>A p.T265K | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- POU3F2 | c.971T>G p.L324R | Missense Mutation (SNP) | VAF 107/312 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PYCR3 | c.89C>A p.A30E | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); called by muse, mutect2
- REV3L | c.2565T>A p.D855E | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RHOBTB3 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 40/104 reads (38%) | called by muse, mutect2, varscan2
- RNF180 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 56/232 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDCCAG8 | c.1752A>T p.E584D | Missense Mutation (SNP) | VAF 88/266 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- SERINC3 | c.229A>G p.K77E | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- SFT2D3 | c.517G>C p.A173P | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIGLEC12 | c.1088A>G p.Y363C (on ENST00000291707 / NM_053003.4; = p.Y245C on NM_033329.2) | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- SIPA1L2 | c.4664A>G p.D1555G | Missense Mutation (SNP) | VAF 53/518 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- SLC39A8 | c.219G>T p.Q73H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- SPRR2F | c.89C>G p.P30R | Missense Mutation (SNP) | VAF 285/548 reads (52%) | PolyPhen benign (0.244); called by muse, mutect2, varscan2
- TBX3 | c.273G>C p.K91N | Missense Mutation (SNP) | VAF 40/285 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TEX14 | c.1966G>T p.G656* (on ENST00000240361 / NM_001201457.2; = p.G650* on NM_031272.5) | Nonsense Mutation (SNP) | VAF 65/151 reads (43%) | called by muse, mutect2, varscan2
- TLL1 | c.1090G>T p.G364* | Nonsense Mutation (SNP) | VAF 49/251 reads (20%) | called by muse, mutect2, varscan2
- TTC3 | c.4254C>A p.H1418Q | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC5A | c.1264T>A p.F422I | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by mutect2, varscan2
- USH2A | c.103G>C p.G35R | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VARS1 | c.1130G>A p.W377* | Nonsense Mutation (SNP) | VAF 23/127 reads (18%) | called by muse, mutect2, varscan2
- VIT | c.258T>A p.C86* | Nonsense Mutation (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
- ZBTB26 | c.831G>C p.K277N | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ZNF521 | c.1808C>A p.A603D | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- ZNF630 | c.100A>T p.R34W | Missense Mutation (SNP) | VAF 57/104 reads (55%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ADCY2 | c.1743G>T p.L581= | Silent (SNP) | VAF 21/359 reads (6%) | called by muse, mutect2
- AK9 | c.3292T>C p.L1098= | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as rs865804619; called by muse, mutect2, varscan2
- ALG13 | c.597C>T p.P199= | Silent (SNP) | VAF 90/158 reads (57%) | called by muse, mutect2, varscan2
- ARID5A | c.246C>G p.L82= | Silent (SNP) | VAF 18/119 reads (15%) | called by muse, mutect2, varscan2
- ASCC3 | c.2430T>A p.A810= | Silent (SNP) | VAF 19/144 reads (13%) | called by muse, mutect2, varscan2
- BCHE | c.361T>C p.L121= | Silent (SNP) | VAF 32/206 reads (16%) | called by muse, mutect2, varscan2
- BHLHE40 | c.537C>G p.V179= | Silent (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- BRCA1 | c.1365T>C p.N455= | Silent (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- CGNL1 | c.2772G>A p.E924= | Silent (SNP) | VAF 22/215 reads (10%) | called by muse, mutect2
- CHAMP1 | c.1386A>T p.S462= | Silent (SNP) | VAF 111/379 reads (29%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.2889C>T p.Y963= | Silent (SNP) | VAF 80/268 reads (30%) | catalogued as rs199548920; called by muse, mutect2, varscan2
- CPT1B | c.2196C>T p.I732= | Silent (SNP) | VAF 123/478 reads (26%) | called by muse, mutect2, varscan2
- CREM | c.345T>G p.L115= (on ENST00000429130; = p.L66= on NM_001881.3) | Silent (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2
- DHX8 | c.1650C>T p.Y550= | Silent (SNP) | VAF 45/131 reads (34%) | catalogued as rs573416546, COSV52255562; called by muse, mutect2, varscan2
- ESRRG | c.681T>A p.V227= | Silent (SNP) | VAF 86/409 reads (21%) | called by muse, mutect2, varscan2
- FBXL14 | c.921C>T p.L307= | Silent (SNP) | VAF 51/284 reads (18%) | catalogued as rs1391674281; called by muse, mutect2, varscan2
- GAK | c.1947C>T p.S649= | Silent (SNP) | VAF 76/224 reads (34%) | catalogued as rs781141385, COSV100033080; called by muse, mutect2, varscan2
- GIPC2 | c.699C>T p.A233= | Silent (SNP) | VAF 43/129 reads (33%) | called by muse, mutect2, varscan2
- HOXB1 | c.660G>A p.K220= | Silent (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- HOXD13 | c.657G>T p.R219= | Silent (SNP) | VAF 52/172 reads (30%) | catalogued as COSV101184147; called by muse, mutect2, varscan2
- KIF21A | c.4518A>G p.G1506= (on ENST00000361418 / NM_001378440.1; = p.G1493= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/257 reads (14%) | called by muse, mutect2, varscan2
- LRRC66 | c.1056G>A p.L352= | Silent (SNP) | VAF 25/115 reads (22%) | called by muse, mutect2, varscan2
- MARCO | c.123G>A p.G41= | Silent (SNP) | VAF 68/234 reads (29%) | called by muse, varscan2
- MED19 | c.471C>A p.G157= | Silent (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- MGAM | c.2310G>T p.L770= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV101527427, COSV72074119; called by muse, mutect2, varscan2
- MYO1C | c.2313A>G p.T771= (on ENST00000648651 / NM_001080779.2; = p.T736= on NM_033375.5) | Silent (SNP) | VAF 182/397 reads (46%) | called by muse, mutect2, varscan2
- PI4KB | c.1249C>A p.R417= (on ENST00000368873 / NM_001369623.1; = p.R429= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 166/440 reads (38%) | catalogued as COSV55020786; called by muse, mutect2, varscan2
- PLA2G1B | c.273C>T p.Y91= | Silent (SNP) | VAF 39/305 reads (13%) | catalogued as rs764040826; called by muse, mutect2, varscan2
- PLCXD2 | c.687G>A p.K229= | Silent (SNP) | VAF 109/384 reads (28%) | called by muse, mutect2, varscan2
- PLIN3 | c.9C>G p.A3= | Silent (SNP) | VAF 75/166 reads (45%) | catalogued as COSV55734984; called by muse, mutect2, varscan2
- PPFIA4 | c.2937C>G p.T979= (on ENST00000447715; = p.T980= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 126/337 reads (37%) | called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.834T>A p.T278= (on ENST00000421990 / NM_001136042.2; = p.T260= on NM_025267.3) | Silent (SNP) | VAF 59/140 reads (42%) | called by muse, mutect2, varscan2
- RAB6D | c.345A>T p.G115= | Silent (SNP) | VAF 52/305 reads (17%) | called by muse, mutect2, varscan2
- SOX7 | c.117G>A p.K39= | Silent (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
- TBCE | c.933C>G p.L311= (on ENST00000366601; = p.L374= on NM_003193.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 207/593 reads (35%) | called by muse, mutect2, varscan2
- TMEM132C | c.217C>A p.R73= | Silent (SNP) | VAF 82/251 reads (33%) | called by muse, mutect2, varscan2
- TMEM202 | c.393T>C p.T131= | Silent (SNP) | VAF 32/210 reads (15%) | catalogued as rs770213701; called by muse, mutect2, varscan2
- UBN2 | c.1482A>G p.L494= | Silent (SNP) | VAF 59/177 reads (33%) | catalogued as rs1395120687, COSV99944682; called by muse, mutect2, varscan2
- UIMC1 | c.1557A>T p.R519= | Silent (SNP) | VAF 42/254 reads (17%) | called by muse, mutect2, varscan2
- USP49 | c.1416C>T p.S472= | Silent (SNP) | VAF 82/259 reads (32%) | called by muse, mutect2, varscan2
- USP8 | c.2451A>C p.S817= | Silent (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- ZNF282 | c.1935C>G p.L645= | Silent (SNP) | VAF 38/114 reads (33%) | catalogued as COSV100021714, COSV50479994; called by muse, mutect2, varscan2
- ZNF526 | c.105A>G p.T35= | Silent (SNP) | VAF 187/641 reads (29%) | called by muse, mutect2, varscan2
- ZNF628 | c.2328G>A p.L776= | Silent (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- AAAS | c.1417-18T>C | Intron (SNP) | VAF 53/365 reads (15%) | called by muse, mutect2, varscan2
- CCL18 | c.-70G>A | 5'UTR (SNP) | VAF 97/212 reads (46%) | called by muse, mutect2, varscan2
- DNM1 | c.2535-1556C>G | Intron (SNP) | VAF 41/117 reads (35%) | called by muse, mutect2, varscan2
- FAS | c.-79C>T | 5'UTR (SNP) | VAF 70/201 reads (35%) | called by muse, mutect2, varscan2
- HSP90AB3P | n.1193C>A | RNA (SNP) | VAF 42/145 reads (29%) | called by muse, mutect2, varscan2
- KIF13B | c.2187+24A>G | Intron (SNP) | VAF 42/187 reads (22%) | called by muse, mutect2, varscan2
- MGAM | c.4619-8751C>T | Intron (SNP) | VAF 55/344 reads (16%) | called by muse, mutect2, varscan2
- MYOT | c.817-28T>G | Intron (SNP) | VAF 82/272 reads (30%) | called by muse, mutect2, varscan2
- NDUFS2 | c.866+24C>T | Intron (SNP) | VAF 31/153 reads (20%) | catalogued as rs746877284; called by muse, mutect2, varscan2
- NEXN | c.688-46A>G | Intron (SNP) | VAF 38/120 reads (32%) | called by muse, mutect2, varscan2
- PADI1 | c.*117A>G | 3'UTR (SNP) | VAF 22/406 reads (5%) | called by muse, mutect2
- PCNX1 | c.2778+12T>A | Intron (SNP) | VAF 47/91 reads (52%) | called by muse, mutect2, varscan2
- PDE1C | c.1892-14473G>T | Intron (SNP) | VAF 36/123 reads (29%) | called by muse, mutect2, varscan2
- PDGFRA | c.628+63T>A | Intron (SNP) | VAF 20/50 reads (40%) | called by mutect2, varscan2
- PDZRN4 | c.844-68505T>A | Intron (SNP) | VAF 23/188 reads (12%) | called by muse, mutect2, varscan2
- PLCB4 | c.1612-2595G>T | Intron (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- RNF8 | c.240+696A>G | Intron (SNP) | VAF 51/315 reads (16%) | called by muse, mutect2, varscan2
- SMARCC2 | c.*39A>T | 3'UTR (SNP) | VAF 14/20 reads (70%) | called by muse, mutect2
- SMIM7 | c.121+168C>A | Intron (SNP) | VAF 30/97 reads (31%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.2062C>A | RNA (SNP) | VAF 215/497 reads (43%) | called by muse, mutect2, varscan2
- TRPA1 | c.-17C>T | 5'UTR (SNP) | VAF 99/301 reads (33%) | catalogued as rs763397178; called by muse, mutect2, varscan2
- XIAP | c.*3952A>C | 3'UTR (SNP) | VAF 126/199 reads (63%) | called by muse, mutect2, varscan2
